Gene-level copy-number profile of tumor specimen TCGA-AA-3538-01A from TCGA case TCGA-AA-3538, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 54.1 years (19,752 days).
Specimen TCGA-AA-3538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.1d1e6f2c-2c3b-45a7-b66b-db450a4f5408.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3538-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3fab69ea-a632-4a06-85e5-2e6ea44c6091

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,766; copy number 2: 39,483; copy number 3: 10,814; copy number 4: 1,725; copy number 5: 114; copy number 6: 918.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3538-01A-01D-0819-01): tumor purity 0.72, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,032 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,924,063–22,559,037, 114 genes, copy number 5 (broad region; genes not listed).
- chr20:28,563,850–64,313,132, 918 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
